Somatic mutation profile of tumor specimen 0DQQBU from CCDI case PBCFFP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.9 years (676 days).
Specimen 0DQQBU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc47d2a0-ad61-41f2-a6eb-d204215f45a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQSUO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88956f5c-36c5-4b53-997b-cef1b701dff4

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Intron 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCND1 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 246/621 reads (40%) | catalogued as rs781783068, COSV99502158; called by muse, mutect2, varscan2
- KRT75 | c.423C>A p.T141= | Silent (SNP) | VAF 227/630 reads (36%) | called by muse, mutect2, varscan2
- BRAF | c.1552+65_1552+66insATTTTATTTT | Intron (INS) | VAF 51/214 reads (24%) | called by mutect2, varscan2
- F13B | c.*88C>T | 3'UTR (SNP) | VAF 6/140 reads (4%) | catalogued as rs867375990; called by muse, mutect2
